TCGA case TCGA-3B-A9HR — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Connective, subcutaneous and other soft tissues; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/bfb21f9b-31af-4ecc-a4f4-d7d3f5728e01

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 38 years; Vital status: Dead; Days to death: 2,694 days (7.4 years).

Diagnoses (4)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C49.2; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Site of resection or biopsy: Connective, subcutaneous and other soft tissues of lower limb and hip; Classification of tumor: primary; Age at diagnosis: 38.4 years (14,041 days); Year of diagnosis: 2007; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 8; Tumor width measurement: 6.5.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 15; Necrosis present: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 2; Tumor length measurement: 5.7; Tumor width measurement: 5.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 39.8 years (14,537 days); Days to diagnosis: 496 days (1.4 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 0.8.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 0.9.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 0.9.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 0.8.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Liver. Age at diagnosis: 42.2 years (15,413 days); Days to diagnosis: 1,372 days (3.8 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 2.6.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 2.3.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 2.6.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 2.3.
4. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Upper limb, NOS. Age at diagnosis: 43.8 years (16,015 days); Days to diagnosis: 1,974 days (5.4 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 4.9; Tumor length measurement: 3.2; Tumor width measurement: 2.3.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.5; Tumor length measurement: 3; Tumor width measurement: 2.5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 2.5; Tumor length measurement: 3; Tumor width measurement: 2.5.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 4.9; Tumor length measurement: 3.2; Tumor width measurement: 2.3.

Follow-up (5 entries)
- Day 496 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 496 days (1.4 years); Discontiguous lesion count: 3.
- Day 1,372 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,372 days (3.8 years).
- Day 1,974 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Upper limb, NOS; Days to progression: 1,974 days (5.4 years); Discontiguous lesion count: 2.
- Days to follow up: 2,577 days (7.1 years); Disease response: With Tumor.
- Days to follow up: 2,694 days (7.4 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3B-A9HR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 90 mg.
  Slide TCGA-3B-A9HR-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3B-A9HR-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3B-A9HR-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Lower Extremity - Thigh/knee.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic width: 5; Lesion radiologic depth: 2; Lesion pathologic length: 8; Lesion pathologic depth: 4.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor; Treatment outcome at TCGA followup: Progressive Disease.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1019; Days from index date to pharmaceutical treatment ended: 1088; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1019; Days from index date to pharmaceutical treatment ended: 1088; Pharmaceutical therapy drug name: Ifosfamide; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 1425; Days from index date to pharmaceutical treatment ended: 1621; Pharmaceutical therapy drug name: trabectedin; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Treatment on clinical trial: Yes; Days from index date to pharmaceutical treatment started: 1758; Days from index date to pharmaceutical treatment ended: 2096; Pharmaceutical therapy drug name: dacarbazine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 2117; Days from index date to pharmaceutical treatment ended: 2396; Pharmaceutical therapy drug name: gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 6: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 2117; Days from index date to pharmaceutical treatment ended: 2396; Pharmaceutical therapy drug name: docetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 7: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 2396; Days from index date to pharmaceutical treatment ended: 2683; Pharmaceutical therapy drug name: pazopanib; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Radiation treatment 1: Days from index date to radiation therapy started: 127; Days from index date to radiation therapy ended: 127; Radiation therapy type: External; Radiation therapy site: Primary Tumor Field; Radiation therapy ongoing indicator: No.
- Radiation treatment 2: Days from index date to radiation therapy started: 2034; Days from index date to radiation therapy ended: 2083; Radiation therapy type: External; Radiation total dose: 4600; Radiation adjuvant units: cGy; Radiation adjuvant fractions total: 23; Radiation therapy site: Distant site; Radiation therapy ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,694 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,694 days; disease-free interval: event (new tumor event after initially disease-free), 496 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 496 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3B-A9HR-01A-11D-A386-01): tumor purity 0.96, ploidy 3.21, whole-genome doublings 1.
